FM case AD1220 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/1ba151a5-45a8-4b82-8127-89c5bf2928cb

Male, 25.8 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the overlapping lesion of nasopharynx; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
